CCDI case PBBSVB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/597dcc53-4fb4-4e8f-bb17-785d51b488b2

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 15.2 years (5,544 days).

Biospecimens (3 samples)
- Sample 0DFYPF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFYQ8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFYQO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
